Somatic mutation profile of tumor specimen MP2PRT-PAVENE-TMP1-A (aliquot MP2PRT-PAVENE-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVENE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,979 days).
Specimen MP2PRT-PAVENE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a773158-6ed6-4997-a10f-57e0af0c20c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVENE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVENE-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ea7e7da-9aeb-4112-ba4a-6e03c3bb8cc2

The open-access MAF lists 106 somatic variants for this specimen: 74 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Nonsense Mutation 5, Intron 4, Frame Shift Ins 2, 3'Flank 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 205/440 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AJM1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 473/1019 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756873636; called by muse, mutect2, varscan2
- ANKRD26 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 201/466 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs759232859; called by muse, mutect2, varscan2
- ATRNL1 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 34/590 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV100744408; called by muse, mutect2
- BCL9L | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 43/967 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs139062309; called by muse, mutect2
- CCDC14 | c.2152G>A p.D718N (on ENST00000488653; = p.D670N on NM_022757.5) | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59944330; called by muse, mutect2
- CDHR1 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 212/470 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV60562269, COSV60566278; called by muse, mutect2, varscan2
- CELSR1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 291/627 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs763639221; called by muse, mutect2, varscan2
- CFAP65 | c.2828C>T p.T943M | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.373); catalogued as rs527910438; called by muse, mutect2, varscan2
- CHMP2A | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs893544316; called by muse, mutect2
- DACH2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs745838015, COSV64173915; called by muse, mutect2, varscan2
- DDX50 | c.2048C>G p.S683* | Nonsense Mutation (SNP) | VAF 60/564 reads (11%) | catalogued as rs753281100; called by muse, mutect2, varscan2
- DPEP2 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 138/281 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV52054604, COSV52055124; called by muse, mutect2, varscan2
- ESRP1 | c.1167G>C p.K389N | Missense Mutation (SNP) | VAF 23/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64410734, COSV99067763; called by muse, mutect2
- EXOC1L | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV72444184; called by muse, mutect2
- FBXO10 | c.2731C>G p.R911G | Missense Mutation (SNP) | VAF 121/286 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750650998, COSV99446607; called by muse, mutect2, varscan2
- GRAMD2B | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 127/262 reads (48%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs79988174; called by muse, mutect2, varscan2
- H3C3 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 45/680 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV63551299, COSV63551685; called by muse, mutect2
- HSD17B2 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 35/540 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as rs1308752990; called by muse, mutect2
- IRF7 | c.347G>A p.R116H (on ENST00000397566; = p.R103H on NM_001572.5) | Missense Mutation (SNP) | VAF 514/1096 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs370737637; called by muse, varscan2
- LAMA5 | c.6856G>C p.D2286H | Missense Mutation (SNP) | VAF 57/785 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.505); catalogued as rs914650086; called by muse, mutect2
- LRRFIP1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 302/623 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759864541; called by muse, mutect2, varscan2
- LTBP1 | c.2749G>C p.D917H (on ENST00000404816 / NM_206943.4; = p.D591H on NM_000627.4) | Missense Mutation (SNP) | VAF 106/223 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs142520374; called by muse, mutect2, varscan2
- MAGEB17 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 264/656 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs895268746, COSV61556844; called by muse, varscan2
- MATK | c.1270C>G p.P424A (on ENST00000310132 / NM_139355.3; = p.P425A on NM_002378.4) | Missense Mutation (SNP) | VAF 250/518 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59555440; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 16/549 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MERTK | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 247/582 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as COSV54932873; called by muse, mutect2, varscan2
- NBN | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV55371142; called by muse, mutect2
- NIBAN2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 25/524 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1232824519, COSV64825839; called by muse, mutect2
- NOC3L | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs753022530, COSV64929660; called by muse, mutect2, varscan2
- NXF3 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 29/694 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV67704896; called by muse, mutect2
- PLXNB1 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs199581131, COSV56488956; called by muse, mutect2
- SLC15A5 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 220/424 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as rs750444095; called by muse, mutect2, varscan2
- THOC2 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 207/481 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as COSV99833242; called by muse, mutect2, varscan2
- TMEM39B | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 246/588 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60379039, COSV60381634; called by muse, mutect2, varscan2
- TOP3A | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 24/460 reads (5%) | catalogued as COSV58177662; called by muse, mutect2
- USP12 | c.78G>C p.E26D | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1194233428; called by muse, mutect2, varscan2
- ZFP42 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 213/529 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1470384671; called by muse, mutect2, varscan2
- ABI3BP | c.2033C>G p.S678* | Nonsense Mutation (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- ANK2 | c.9271G>C p.E3091Q | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANO4 | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AP3M1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BEX4 | c.362G>C p.*121Sext*51 | Nonstop Mutation (SNP) | VAF 108/224 reads (48%) | called by muse, mutect2, varscan2
- BORA | c.331G>C p.E111Q (on ENST00000613797; = p.E36Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C4BPB | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 17/598 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); called by muse, mutect2
- CRNN | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 278/574 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM2 | c.1699C>G p.L567V (on ENST00000355667 / NM_001005360.3; = p.L563V on NM_004945.3) | Missense Mutation (SNP) | VAF 25/507 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2
- FAT4 | c.6760G>T p.D2254Y | Missense Mutation (SNP) | VAF 27/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXO3 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 25/938 reads (3%) | called by muse, mutect2
- FSTL4 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 212/456 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPRC6A | c.2085G>C p.Q695H | Missense Mutation (SNP) | VAF 42/541 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.238); called by muse, mutect2
- GREB1L | c.4633C>T p.H1545Y | Missense Mutation (SNP) | VAF 45/732 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGBP1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 198/461 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LGI2 | c.1539C>A p.F513L | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYPLA2 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 163/312 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MMACHC | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 226/509 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MTHFR | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NUP153 | c.2044C>G p.Q682E | Missense Mutation (SNP) | VAF 34/604 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, mutect2
- PCARE | c.49A>G p.S17G | Missense Mutation (SNP) | VAF 170/386 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PIKFYVE | c.4865C>A p.S1622* | Nonsense Mutation (SNP) | VAF 161/424 reads (38%) | called by muse, mutect2, varscan2
- POTEE | c.2370C>G p.F790L | Missense Mutation (SNP) | VAF 389/1139 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- PRDM12 | c.804C>G p.D268E | Missense Mutation (SNP) | VAF 60/1322 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.033); called by muse, mutect2
- PRKACA | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RAD54L2 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 24/648 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYBP | c.76dup p.A26Gfs*2 | Frame Shift Ins (INS) | VAF 240/615 reads (39%) | called by mutect2, pindel, varscan2
- SCAPER | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 138/301 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SETBP1 | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 312/599 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SRP68 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 152/334 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- TMEM102 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 426/890 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TPGS1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 436/851 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- UBAP2L | c.1131_1132insG p.Q378Afs*28 | Frame Shift Ins (INS) | VAF 204/460 reads (44%) | called by mutect2, pindel*, varscan2
- UBXN6 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VSIG10L | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 20/643 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); called by muse, mutect2
- ZSWIM9 | c.1562G>C p.R521T | Missense Mutation (SNP) | VAF 60/908 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); called by muse, mutect2
- ABCF3 | c.1137C>T p.V379= | Silent (SNP) | VAF 166/407 reads (41%) | catalogued as rs367881517, COSV53052501; called by muse, mutect2, varscan2
- ATXN7L1 | c.2478G>C p.G826= | Silent (SNP) | VAF 151/372 reads (41%) | called by mutect2, varscan2
- CRAT | c.1179C>T p.I393= | Silent (SNP) | VAF 48/638 reads (8%) | catalogued as rs1198735780, COSV58877087; called by muse, mutect2
- DCAF11 | c.804C>T p.V268= | Silent (SNP) | VAF 22/369 reads (6%) | called by muse, mutect2
- DMRT3 | c.1032C>T p.A344= | Silent (SNP) | VAF 289/684 reads (42%) | catalogued as rs766101082, COSV51904706; called by muse, mutect2
- DNAH10 | c.10983G>T p.L3661= (on ENST00000409039; = p.L3600= on NM_207437.3) | Silent (SNP) | VAF 53/918 reads (6%) | called by muse, mutect2
- EIF2AK3 | c.645C>T p.I215= | Silent (SNP) | VAF 40/343 reads (12%) | called by muse, mutect2, varscan2
- FBN3 | c.3486G>A p.Q1162= | Silent (SNP) | VAF 169/369 reads (46%) | called by muse, mutect2, varscan2
- FUBP3 | c.1323C>T p.F441= | Silent (SNP) | VAF 22/686 reads (3%) | called by muse, mutect2
- FUBP3 | c.1671C>T p.F557= | Silent (SNP) | VAF 36/788 reads (5%) | called by muse, mutect2
- GLB1L2 | c.1869C>T p.F623= | Silent (SNP) | VAF 214/493 reads (43%) | catalogued as rs140543170, COSV56996746, COSV56997826; called by muse, mutect2, varscan2
- HRH2 | c.201C>T p.L67= | Silent (SNP) | VAF 34/562 reads (6%) | catalogued as rs149131528; called by muse, mutect2
- IQSEC2 | c.975C>T p.L325= (on ENST00000642864 / NM_001111125.3; = p.L120= on NM_015075.2) | Silent (SNP) | VAF 32/636 reads (5%) | called by muse, mutect2
- KANK1 | c.3831C>T p.H1277= | Silent (SNP) | VAF 185/451 reads (41%) | catalogued as rs766451306; called by muse, mutect2, varscan2
- KCNN1 | c.969G>C p.L323= | Silent (SNP) | VAF 15/599 reads (3%) | called by muse, mutect2
- KPRP | c.1368G>A p.E456= | Silent (SNP) | VAF 288/632 reads (46%) | called by muse, mutect2, varscan2
- NR0B1 | c.1281C>T p.I427= | Silent (SNP) | VAF 202/452 reads (45%) | catalogued as rs746827941; called by muse, mutect2, varscan2
- PCCB | c.822C>T p.F274= | Silent (SNP) | VAF 32/511 reads (6%) | called by muse, mutect2
- PTGR2 | c.901C>T p.L301= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as COSV50865410; called by muse, mutect2
- SLC44A2 | c.363C>T p.L121= | Silent (SNP) | VAF 24/556 reads (4%) | catalogued as rs1568450161, COSV59839001; called by muse, mutect2
- SLF1 | c.2832G>A p.E944= | Silent (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- TACC2 | c.2004C>T p.P668= | Silent (SNP) | VAF 52/832 reads (6%) | catalogued as rs776015159, COSV100553400, COSV57757486; called by muse, mutect2
- TEX55 | c.339G>A p.Q113= | Silent (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- UNC45B | c.2178C>G p.L726= | Silent (SNP) | VAF 38/538 reads (7%) | called by muse, mutect2
- USP10 | c.63C>T p.F21= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV54747014; called by muse, mutect2, varscan2
- ZMYM3 | c.3693C>T p.L1231= | Silent (SNP) | VAF 26/976 reads (3%) | called by muse, mutect2
- ERCC6 | c.1397+7537G>C | Intron (SNP) | VAF 184/458 reads (40%) | called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714683 ins CT | 3'Flank (INS) | VAF 65/94 reads (69%) | called by mutect2, pindel, varscan2
- TANK | c.-49-19156G>C | Intron (SNP) | VAF 240/487 reads (49%) | called by muse, mutect2, varscan2
- TPM4 | c.*371G>C | 3'UTR (SNP) | VAF 22/463 reads (5%) | called by muse, mutect2
- ZFYVE28 | c.701+4747C>T | Intron (SNP) | VAF 298/664 reads (45%) | catalogued as rs931577720; called by muse, mutect2, varscan2
- ZSWIM9 | c.1855-411G>C | Intron (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
